Somatic mutation profile of tumor specimen TCGA-YL-A8S9-01A (aliquot TCGA-YL-A8S9-01A-11D-A377-08) from TCGA case TCGA-YL-A8S9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,204 days).
Specimen TCGA-YL-A8S9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 360a3cd8-91b6-4c4b-9e65-f0940e3608d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8S9-10A (Blood Derived Normal), aliquot TCGA-YL-A8S9-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8decebf-cd18-4326-a96e-8319a7464660

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, Intron 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8624A>G p.N2875S | Missense Mutation (SNP) | VAF 69/75 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782451, CD120363, CM102244, COSV53726848, COSV53730217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXA1 | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 14/25 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292426539, COSV51644190, COSV51644993, COSV51646200; called by muse, mutect2, varscan2
- ADGRE2 | c.1040A>T p.N347I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV100215672; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5296C>A p.P1766T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99781989; called by muse, mutect2, varscan2
- ARRDC5 | c.77C>T p.P26L (on ENST00000381781; = p.P12L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV101108076; called by muse, mutect2, varscan2
- ATF2 | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV99908336; called by muse, mutect2, varscan2
- ATP1A3 | c.2794G>A p.V932I (on ENST00000545399 / NM_001256214.2; = p.V919I on NM_152296.5) | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs1568853008, COSV57488993; called by muse, mutect2, varscan2
- CDH11 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556647809, COSV51756679, COSV51758059; called by muse, mutect2, varscan2
- CHMP4B | c.642G>C p.M214I | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV99459613; called by muse, mutect2, varscan2
- DOCK10 | c.2933A>T p.N978I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99287538; called by muse, mutect2, varscan2
- FOXP2 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100646203; called by muse, mutect2
- GRM1 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99263928; called by muse, mutect2, varscan2
- ITGA4 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753886999, COSV99275716; called by muse, mutect2, varscan2
- MYH4 | c.2990C>T p.T997I | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV99700309; called by muse, mutect2
- RFC5 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV99969751; called by muse, mutect2, varscan2
- RHOT1 | c.1264A>G p.N422D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100446885; called by muse, mutect2, varscan2
- RUFY2 | c.1925G>T p.*642Lext*70 | Nonstop Mutation (SNP) | VAF 24/68 reads (35%) | catalogued as rs1441187436, COSV99769110; called by muse, mutect2
- SLC34A2 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs371683311; called by muse, mutect2, varscan2
- SLC35F4 | c.1493A>T p.D498V (on ENST00000339762 / NM_001352015.2; = p.D462V on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100333525; called by muse, mutect2, varscan2
- THBS3 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100857469; called by muse, mutect2, varscan2
- VPS11 | c.642G>T p.Q214H (on ENST00000620429; = p.Q758H on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100333507; called by muse, mutect2
- ANK3 | c.372dup p.V125Sfs*37 | Frame Shift Ins (INS) | VAF 77/168 reads (46%) | called by mutect2, pindel, varscan2
- DDX23 | c.739del p.L247Cfs*53 | Frame Shift Del (DEL) | VAF 59/138 reads (43%) | called by mutect2, pindel, varscan2
- IGKV3-7 | c.344T>A p.L115* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | called by muse, varscan2
- RBP1 | c.57_58del p.Y20Pfs*28 (on ENST00000619087 / NM_001365940.2; = p.Y82Pfs*28 on NM_002899.5) | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- ATP10A | c.1834A>C p.R612= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100790820; called by muse, mutect2, varscan2
- DDX54 | c.834C>T p.S278= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs751506364, COSV100013571; called by muse, mutect2, varscan2
- NLK | c.654C>T p.V218= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101310859; called by muse, varscan2
- ONECUT1 | c.1083C>T p.R361= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV100009016; called by muse, mutect2, varscan2
- PTPRU | c.3078C>T p.V1026= | Silent (SNP) | VAF 55/151 reads (36%) | catalogued as rs749070547, COSV100111493; called by muse, mutect2, varscan2
- RBM6 | c.*1_*3del | Silent (DEL) | VAF 27/83 reads (33%) | called by mutect2, pindel, varscan2
- SASH3 | c.907C>A p.R303= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as rs142835579, COSV63556548; called by muse, mutect2, varscan2
- SQOR | c.774C>T p.N258= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV99525490; called by muse, mutect2, varscan2
- SHOC1 | c.251-442A>G | Intron (SNP) | VAF 29/73 reads (40%) | catalogued as rs1251553197, COSV100597236; called by muse, mutect2, varscan2
